Gene-level copy-number profile of tumor specimen TCGA-DA-A1HV-06A from TCGA case TCGA-DA-A1HV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 75.4 years (27,556 days).
Specimen TCGA-DA-A1HV-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ce473e09-bab7-44fa-a02f-8e38f34602fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DA-A1HV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db20bf2c-726c-4cc4-967d-5514c2c0c901

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 134; copy number 2: 24,606; copy number 3: 16,562; copy number 4: 10,013; copy number 5: 5,964; copy number 6: 961; copy number 7: 1,578.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DA-A1HV-06A-21D-A194-01): tumor purity 0.67, ploidy 2.92, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,503 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:28,996,498–190,092,279, 2,165 genes, copy number 5–7 (broad region; genes not listed).
- chr5:58,198–1,309,377, 48 genes, copy number 7: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457.
- chr5:4,012,708–4,041,764, 2 genes, copy number 5: AC025773.1, AC025187.1.
- chr5:17,156,971–17,157,071, 1 gene, copy number 5: RNA5SP180.
- chr5:19,471,296–25,445,925, 58 genes, copy number 5–6 (within-gene range 2–6): CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1, AC010460.2, Y_RNA, AC010460.3, AC010460.1, PRDM9, AC109445.1, AC108103.1, C5orf17, AC026784.1, ADH5P5, Y_RNA, AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2.
- chr5:25,963,839–27,496,994, 12 genes, copy number 5 (within-gene range 2–5): AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL.
- chr5:29,516,005–31,329,146, 16 genes, copy number 7: AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1, AC026433.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51.
- chr5:31,532,287–45,895,970, 248 genes, copy number 5 (broad region; genes not listed).
- chr6:167,607–79,406,774, 1,723 genes, copy number 5–7 (broad region; genes not listed).
- chr10:28,532,493–28,941,910, 12 genes, copy number 5 (within-gene range 3–5): WAC, RNU4ATAC6P, TPRKBP1, RNU6-1067P, BAMBI, LINC01517, AL355376.1, RNU6-270P, LINC00837, AL355376.2, RNA5SP308, RPL21P93.
- chr10:96,364,608–100,286,680, 88 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr12:19,775,451–34,249,958, 270 genes, copy number 6 (broad region; genes not listed).
- chr12:80,099,537–80,380,879, 1 gene, copy number 5 (within-gene range 3–5): OTOGL.
- chr12:80,343,515–84,672,026, 38 genes, copy number 5: RN7SKP261, PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5, LINC01490, LIN7A, MIR617, AC078886.1, MIR618, ACSS3, AC078955.1, MIR4699, PPFIA2, PPFIA2-AS1, AC069228.1, AC079363.1, AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1, AC090679.3, AC090679.2, AC090679.1, AC087888.1, AC093027.1.
- chr12:96,060,024–98,735,433, 52 genes, copy number 5: YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54, EEF1A1P33, NEDD1, Y_RNA, AC007656.2, AC007656.1, AC007656.3, AC007656.4, LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6, AC018659.2, PAFAH1B2P2, RNU6-36P, MIR4495, MIR4303, AC016152.1, AC008055.1, RNU4-41P, AC008055.2, SLC9A7P1, LINC02453, TMPO-AS1, TMPO, PPIAP8, SLC25A3, SNORA53, IKBIP, APAF1.
- chr12:98,794,485–98,976,656, 2 genes, copy number 5: AC008126.1, AC069437.1.
- chr14:49,643,555–50,116,600, 24 genes, copy number 5 (within-gene range 2–5): POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT.
- chr15:88,960,070–101,933,350, 327 genes, copy number 5 (broad region; genes not listed).
- chr17:37,084,992–37,406,836, 1 gene, copy number 5 (within-gene range 2–5): ACACA.
- chr17:37,375,985–83,095,122, 1,648 genes, copy number 5 (broad region; genes not listed).
- chr20:30,214,765–56,205,173, 643 genes, copy number 6 (broad region; genes not listed).
- chr22:15,290,718–41,834,665, 1,124 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
